Gene-level copy-number profile of specimen HCM-BROD-0449-C34-85M from HCMI case HCM-BROD-0449-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.3 years (26,423 days).
Specimen HCM-BROD-0449-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8f3ca603-18cd-410e-a3e9-31748798ce9d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0449-C34-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/2366cbe8-fa59-4662-913b-5c74f1f05001

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,333; copy number 2: 27,784; copy number 3: 12,386; copy number 4: 14,197; copy number 5: 1,506; copy number 6: 531; copy number 7: 516; copy number 8: 92; copy number 9: 21; copy number 10: 4; copy number 11: 5; copy number 13: 1; copy number 14: 7.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr19:1,505,022–1,513,604, 1 gene: ADAMTSL5.
- chr19:1,508,375–1,508,963, 1 gene: AC027307.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,683 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,694,112–116,742,609, 3 genes, copy number 5: LINC02868, GAPDHP64, NEFHP1.
- chr1:117,272,182–117,321,336, 1 gene, copy number 5: LINC01525.
- chr1:117,549,415–117,549,922, 1 gene, copy number 5: VPS25P1.
- chr1:117,688,621–117,688,742, 1 gene, copy number 5: AL390877.1.
- chr1:119,533,749–119,534,746, 1 gene, copy number 5: GAPDHP32.
- chr1:119,619,377–119,648,266, 1 gene, copy number 5: ZNF697.
- chr1:119,886,304–120,127,074, 5 genes, copy number 5: NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P.
- chr1:120,419,850–121,185,539, 25 genes, copy number 5 (within-gene range 4–5): NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B.
- chr3:10,248,023–10,294,903, 6 genes, copy number 5 (within-gene range 4–5): TATDN2, AC022384.1, LINC00852, GHRL, GHRLOS, AC022384.2.
- chr3:11,790,442–11,912,313, 6 genes, copy number 5: TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1.
- chr3:12,257,801–12,434,356, 3 genes, copy number 5: GSTM5P1, PPARG, AC091492.1.
- chr3:13,816,258–14,352,568, 14 genes, copy number 5: WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267.
- chr3:128,748,538–164,171,556, 588 genes, copy number 5–6 (broad region; genes not listed).
- chr3:164,714,095–198,123,232, 621 genes, copy number 5–7 (broad region; genes not listed).
- chr5:8,659,764–8,660,059, 1 gene, copy number 5: AC091953.2.
- chr5:15,425,758–45,895,970, 414 genes, copy number 5–14 (within-gene range 5–19) (broad region; genes not listed).
- chr6:63,635,802–63,779,336, 1 gene, copy number 6 (within-gene range 2–6): PHF3.
- chr8:37,326,575–37,567,477, 6 genes, copy number 6: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3.
- chr8:98,943,595–145,066,685, 709 genes, copy number 5–7 (broad region; genes not listed).
- chr12:6,199,715–6,238,271, 2 genes, copy number 5: CD9, Y_RNA.
- chr12:6,618,835–6,647,433, 2 genes, copy number 5: LPAR5, ACRBP.
- chr12:10,699,089–10,723,323, 1 gene, copy number 5: YBX3.
- chr12:14,169,746–15,006,999, 28 genes, copy number 5–6: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11, ATF7IP, PLBD1, AC008114.1, RN7SKP134, PLBD1-AS1, GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489.
- chr12:19,107,854–19,108,183, 1 gene, copy number 5: MEF2BNBP1.
- chr12:31,073,860–31,327,058, 11 genes, copy number 5: DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224.
- chr13:81,689,911–81,691,072, 1 gene, copy number 6: PTMAP5.
- chr13:113,877,608–113,887,149, 3 genes, copy number 5: BX072579.1, LINC00454, BX072579.2.
- chr17:17,504,005–20,319,026, 154 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr19:1,609,290–2,883,445, 73 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,333. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
